Gene-level copy-number profile of tumor specimen TCGA-30-1860-01A from TCGA case TCGA-30-1860, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.6 years (21,406 days).
Specimen TCGA-30-1860-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e6d4da43-aa9e-4f0c-9cfd-c281e41ac0ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1860-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ca9da173-93b9-498d-9efd-9ed75b009757

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 353; copy number 1: 25,246; copy number 2: 27,123; copy number 3: 5,691; copy number 4: 1,311; copy number 5: 91.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-30-1860-01): tumor purity 0.79, ploidy 1.75, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 353 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:138,101,878–144,332,568, 61 genes (within-gene range 0–1) (broad region; genes not listed).
- chr2:205,253,304–205,798,133, 3 genes (within-gene range 0–1): AC008171.1, NRP2, AC007362.1.
- chr5:102,371,774–108,382,098, 38 genes (within-gene range 0–1): SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2, AC011362.1, MACIR, AC010406.1, PDZPH1P, LINC02115, NUDT12, AC008505.1, LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1, RNA5SP189, AC027313.1, AC114940.1, AC114940.2, LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17.
- chr6:112,476,538–115,643,916, 31 genes: AL357514.1, PA2G4P5, AL360085.1, RNU6-1163P, AL360015.1, FCF1P10, AL049695.1, SOCS5P5, AL589684.1, LINC02518, AL513123.1, RPS27AP11, LINC02541, FO393415.2, FO393415.1, MARCKS, MROCKI, LINC02880, HDAC2, HDAC2-AS2, NUDT19P3, HS3ST5, RPSAP43, RNA5SP213, DNAJA1P4, AL138830.2, AL138830.1, AL590550.1, RNU6-475P, AL606845.1, LINC02534.
- chr6:150,599,883–151,101,887, 8 genes (within-gene range 0–1): PLEKHG1, AL450344.3, AL450344.1, AL450344.2, PDCL3P5, MTHFD1L, ARL4AP5, RNU6-302P.
- chr8:150,584–5,911,236, 78 genes (broad region; genes not listed).
- chr8:11,842,524–11,950,753, 6 genes (within-gene range 0–1): CTSB, AC025857.1, OR7E158P, OR7E161P, AC107918.5, AC107918.6.
- chr10:75,552,458–75,643,106, 3 genes: MIR606, AL589863.2, AL589863.1.
- chr10:87,500,337–89,701,274, 59 genes: AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107, AL157400.5, AL157400.2, AL157400.1, AL157400.3, AL157400.4.
- chr11:9,958,744–10,000,290, 2 genes: AC011092.1, AC011092.3.
- chr12:100,267,140–100,341,715, 1 gene: SCYL2.
- chr13:48,389,567–48,444,704, 2 genes (within-gene range 0–1): LPAR6, Metazoa_SRP.
- chr13:50,045,143–50,081,978, 7 genes: AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,173,181, 5 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4.
- chr15:60,479,152–62,954,124, 46 genes (within-gene range 0–1): RORA-AS1, RORA, AC107241.1, CYCSP38, AC009560.1, AC009560.3, AC009560.4, AC009560.2, RORA-AS2, RNA5SP397, AC022898.1, AC022898.2, AC012404.1, AC012404.2, AC107905.1, AC104574.2, AC104574.1, AC018618.1, AC018618.2, LINC02349, AC009554.1, VPS13C, AC009554.2, AC104590.1, C2CD4A, NPM1P47, C2CD4B, AC126323.2, AC126323.1, AC126323.3, Metazoa_SRP, GOLGA2P11, AC126323.4, AC126323.6, AC126323.5, MIR8067, MIR6085, HMGN1P26, AC032011.1, TLN2, MGC15885, AC100839.1, MIR190A, AC103740.1, AC103740.2, AC079328.1.
- chr17:12,020,829–12,143,830, 3 genes (within-gene range 0–1): MAP2K4, RNU11-2P, MIR744.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 91 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,666,559–172,604,006, 78 genes, copy number 5 (broad region; genes not listed).
- chr12:19,404,045–19,720,801, 1 gene, copy number 5 (within-gene range 4–5): AEBP2.
- chr12:19,508,904–20,688,583, 12 genes, copy number 5: AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1.

Autosomal genes at a single copy (total copy number 1): 24,278. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
